Somatic mutation profile of tumor specimen TCGA-CJ-4636-01A (aliquot TCGA-CJ-4636-01A-02D-1386-10) from TCGA case TCGA-CJ-4636, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 51.7 years (18,878 days).
Specimen TCGA-CJ-4636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cd113e7-cd8b-4073-a8c2-10859e081438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4636-11A (Solid Tissue Normal), aliquot TCGA-CJ-4636-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e278cca2-2ad2-426e-a47d-8e33cd671287

The open-access MAF lists 56 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 34, Silent 8, Splice Site 5, Nonsense Mutation 5, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 79/183 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690962, CM003060, COSV104374386, COSV56542402, COSV56545166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.2575+1G>A p.X859_splice | Splice Site (SNP) | VAF 26/110 reads (24%) | catalogued as COSV66860061; called by muse, varscan2
- ADCY9 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV53575714; called by muse, mutect2
- AP1G1 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 93/426 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV55489660; called by muse, mutect2, varscan2
- BAP1 | c.122+2T>C p.X41_splice | Splice Site (SNP) | VAF 68/194 reads (35%) | catalogued as COSV56233985, COSV56234855; called by muse, mutect2
- BDP1 | c.4124A>G p.K1375R | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV62431645; called by muse, mutect2, varscan2
- CA7 | c.720G>T p.R240S | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.452); catalogued as COSV58156291, COSV58156502; called by muse, mutect2, varscan2
- CAPN9 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 137/508 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55234046; called by muse, mutect2, varscan2
- CCNF | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV53540141; called by muse, mutect2, varscan2
- CIR1 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 58/748 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100565108; called by muse, mutect2
- CNKSR1 | c.1345G>A p.G449S (on ENST00000374253 / NM_001297647.2; = p.G442S on NM_006314.3) | Missense Mutation (SNP) | VAF 99/350 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1234762793, COSV58792267, COSV58793349; called by muse, mutect2, varscan2
- COL21A1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 32/114 reads (28%) | catalogued as rs202026963; called by muse, mutect2, varscan2
- CWH43 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 234/1138 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV56939206; called by muse, mutect2
- DENND2D | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100718600, COSV62959201; called by muse, mutect2, varscan2
- DTNB | c.892A>T p.K298* | Nonsense Mutation (SNP) | VAF 70/303 reads (23%) | catalogued as COSV56477460; called by muse, varscan2
- GRM6 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 132/303 reads (44%) | catalogued as COSV51442332; called by muse, mutect2, varscan2
- HNRNPC | c.273C>A p.N91K | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV60145266; called by muse, mutect2, varscan2
- IL19 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 52/157 reads (33%) | catalogued as COSV54283653; called by muse, mutect2, varscan2
- ITPR3 | c.6812G>A p.R2271H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs942711758, COSV65409623; called by muse, mutect2, varscan2
- KIAA1210 | c.4837C>A p.P1613T | Missense Mutation (SNP) | VAF 155/283 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV68177310; called by muse, mutect2, varscan2
- LAMA2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 18/400 reads (5%) | catalogued as rs868019991, COSV70351944; called by muse, mutect2
- LRRC10 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV64060395; called by muse, mutect2, varscan2
- MAML3 | c.3347A>G p.D1116G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV72209182; called by muse, mutect2, varscan2
- MAST4 | c.6998A>T p.H2333L (on ENST00000403625 / NM_001164664.2; = p.H2144L on NM_015183.3) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV55126679; called by muse, mutect2, varscan2
- MBL2 | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767473969, COSV64758603; called by muse, mutect2, varscan2
- METTL3 | c.1518+1G>C p.X506_splice | Splice Site (SNP) | VAF 50/320 reads (16%) | catalogued as COSV52969092; called by muse, varscan2
- METTL3 | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52969099; called by muse, varscan2
- METTL3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52969103; called by muse, mutect2, varscan2
- MKKS | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV61398831; called by muse, mutect2, varscan2
- MMRN1 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1438315634, COSV53344007, COSV99307848; called by muse, varscan2
- NPFFR2 | c.1322A>T p.N441I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58150125; called by muse, mutect2, varscan2
- OGN | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV52761031; called by muse, mutect2, varscan2
- OR8D4 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58430418; called by muse, mutect2
- PAK6 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs866737297, COSV53045852; called by muse, mutect2, varscan2
- PCDH15 | c.5615A>G p.K1872R | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV100228096; called by muse, mutect2
- RPTOR | c.3646A>C p.K1216Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.374); catalogued as COSV60809146; called by muse, mutect2, varscan2
- SLC13A2 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58995232; called by muse, mutect2, varscan2
- SPX | c.87+1G>T p.X29_splice | Splice Site (SNP) | VAF 200/469 reads (43%) | catalogued as COSV57020880; called by muse, mutect2, varscan2
- SRCAP | c.2411A>T p.K804M | Missense Mutation (SNP) | VAF 21/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99351413; called by muse, mutect2
- ST3GAL1 | c.331A>G p.N111D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | PolyPhen benign (0.027); catalogued as COSV60613205; called by muse, mutect2
- TMC8 | c.1466T>A p.L489H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59209795; called by muse, mutect2, varscan2
- WDR77 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52385387; called by muse, mutect2, varscan2
- ZFPM2 | c.2761A>C p.N921H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.34); catalogued as rs757308103, COSV65873865; called by muse, mutect2, varscan2
- CFHR2 | c.613_613+5del p.X205_splice | Splice Site (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- KIFAP3 | c.681del p.I227Mfs*5 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- PARP4 | c.2291del p.N764Tfs*6 | Frame Shift Del (DEL) | VAF 58/222 reads (26%) | called by mutect2, pindel, varscan2
- SART3 | c.499del p.E167Sfs*11 | Frame Shift Del (DEL) | VAF 43/249 reads (17%) | called by mutect2, pindel, varscan2
- SUZ12 | c.980del p.I327Kfs*80 | Frame Shift Del (DEL) | VAF 101/438 reads (23%) | called by mutect2, pindel, varscan2
- ABCC9 | c.477C>A p.G159= | Silent (SNP) | VAF 11/244 reads (5%) | catalogued as COSV99687403; called by muse, mutect2
- ADCY9 | c.1914T>A p.A638= | Silent (SNP) | VAF 99/198 reads (50%) | catalogued as COSV53575726; called by muse, mutect2
- CCDC62 | c.2013C>A p.V671= | Silent (SNP) | VAF 108/716 reads (15%) | catalogued as COSV53433866; called by muse, mutect2, varscan2
- FBXL13 | c.349T>C p.L117= | Silent (SNP) | VAF 33/282 reads (12%) | catalogued as rs911838683, COSV57538569; called by muse, mutect2, varscan2
- METTL3 | c.1653G>A p.L551= | Silent (SNP) | VAF 37/265 reads (14%) | catalogued as rs1348790143, COSV52969091; called by muse, mutect2, varscan2
- NEDD4L | c.651G>A p.R217= | Silent (SNP) | VAF 19/255 reads (7%) | catalogued as COSV56845436; called by muse, mutect2
- PAPOLB | c.1788C>T p.H596= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as COSV68201074; called by muse, mutect2, varscan2
- PDE1B | c.1605G>A p.L535= | Silent (SNP) | VAF 58/168 reads (35%) | catalogued as COSV54493109; called by muse, mutect2, varscan2
